Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5178, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5178-01A (Primary Tumor).

[page 1 of 2]
Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal cancer with metastasis to liver.

TCGA-BP-5178

Specimens Submitted:

1: SP: Right lobe of liver, partial duodenectomy, total right adrenalectomy, radical right nephrectomy, portion of chest wall and diaphragm

2: SP: Gallbladder

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY, PARTIAL DUODENECTOMY, AND PARTIAL HEPATECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE IV/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 10 CM.
- TUMOR INVOLVES THE LIVER AND THE MUSCULARIS PROPRIA OF THE DUODENUM BY DIRECT EXTENSION (pT4).
- VASCULAR INVASION IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE TUMOR IS PRESENT WITHIN 1.5 MM OF THE HEPATIC MARGIN OF RESECTION.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): 0/2.
- THE HEPATIC PARENCHYMA HAS MILD NON-SPECIFIC CHRONIC PORTAL INFLAMMATION, NO STEATOSIS,, AND NO CIRRHOSIS.
- 2) GALLBLADDER; RESECTION:
- BENIGN GALLBLADDER.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Right lobe of liver, partial duodenectomy, total right adrenalectomy, radical right nephrectomy, portion of chest wall and diaphragm". It consists of a portion of liver, a portion of duodenum, right kidney with adrenal gland, and attached perinephric fat measuring 28.0 x 25.0 x 6.0 cm overall. The kidney measures 15.0 x 8.0 x 6.0 cm. The liver measures 25.0 x 8.0 x 9.0 cm. The overall weight of the specimen is 2,154 gm. The ureter is identified and it measures 1.0 x 0.5 cm and shows unremarkable tan-pink mucosa. Sections from the ureteral and vascular margins are submitted. The adrenal gland is identified, it weighs approximately 4.5 grams and measures 3.5 x 3.0 x 1.0 cm. The specimen is sectioned to reveal a 10.0 x 8.0 x 6.0 cm tan, hemorrhagic tumor mass that involves the lower pole, of the kidney, extending to the upper pole and to the renal sinus. The tumor appears to extend to the surrounding perirenal fat. Sections through the liver

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

show local extension of the tumor into the parenchyma. The tumor is at a distance of less than 1 mm from the inked hepatic resection margin and at a distance of 0.3 cm from the duodenal margin. Photographs are taken. Portions of tumor in the kidney and in the liver are submitted for TPS and are designated T1 and T2 respectively. Representative sections are submitted.

Summary of Sections:

UVM - ureteral and vascular margin
LN - lymph nodes in perinephric fat
LM - liver margin
ADR - adrenal gland
DM - duodenal margin
TSI - tumor to renal sinus
TNK - tumor with normal kidney
RT - random tumor
TL - tumor to liver
TNL - tumor to normal liver
NL - normal liver

2) The specimen is received in formalin, labeled "Gallbladder". It consists of a 4.0 x 3.0 x 1.2 cm gallbladder with a pink serosa and a velvety green mucosa with a wall thickness that ranges from 0.2 cm to 0.3 cm. No calculi are identified. Representative sections are submitted.

Summary of Sections:

GB - gallbladder

Summary of Sections:

Part 1: SP: Right lobe of liver, partial duodenectomy, total right adrenalectomy, radical right nephrectomy, portion of chest wall and diaphragm

Block	Sect. Site	PCs
4	adr	4
2	dm	2
2	lm	2
1	ln	1
1	nl	1
9	rt	9
2	tl	2
3	tnk	3
2	tnl	2
2	tsi	2
1	UVM	1

Part 2: SP: Gallbladder

Block	Sect. Site	PCs
1	gb	1

Source: NCI Genomic Data Commons file 88977863-9db9-4b8b-998a-bd4edf53d493 (TCGA-BP-5178.AB93A182-229F-4062-8DC2-CC70DEE9D237.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).